Somatic mutation profile of tumor specimen TARGET-20-PAPZFV-09A (aliquot TARGET-20-PAPZFV-09A-01D) from TARGET case TARGET-20-PAPZFV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.5 years (6,765 days).
Specimen TARGET-20-PAPZFV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c34e77a-25f9-41ff-8727-d25054481556.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAPZFV-14A (Bone Marrow Normal), aliquot TARGET-20-PAPZFV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69b473b7-e66f-4ffa-90e5-e3421758d56b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.923_927del p.V308Dfs*11 | Frame Shift Del (DEL) | VAF 74/176 reads (42%) | called by mutect2, pindel*
- GATA2 | c.919_920insACCGGCGGGACG p.R307delinsHRRDG | In Frame Ins (INS) | VAF 14/62 reads (23%) | called by pindel, varscan2
